Somatic mutation profile of tumor specimen ALCH-B79K-TTP1-A (aliquot ALCH-B79K-TTP1-A-1-0-D-A96E-47) from ALCHEMIST case ALCH-B79K, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.4 years (19,880 days).
Specimen ALCH-B79K-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d09cf57-34b9-48e5-b9be-e5fc696ff77b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B79K-NB1-A (Peripheral Whole Blood; tissue type Normal), aliquot ALCH-B79K-NB1-A-1-0-D-A96E-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1adb006d-c883-4d78-82d9-e9e9102fb413

The open-access MAF lists 40 somatic variants for this specimen: 29 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 9, In Frame Del 2, Nonsense Mutation 2, RNA 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.815T>G p.V272G | Missense Mutation (SNP) | VAF 17/95 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876660333, CM942122, COSV52701102, COSV52773741, COSV52787833, COSV53259929; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- INA | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV100878619; called by muse, varscan2
- MUC16 | c.1229C>A p.S410Y | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.955); catalogued as COSV67445515; called by muse, mutect2
- MUC17 | c.4531G>A p.E1511K | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.246); catalogued as COSV60295164; called by muse, mutect2
- PRKAG1 | c.494A>G p.Y165C | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1304336849; called by muse, mutect2, varscan2
- PWWP3A | c.869C>T p.S290L (on ENST00000627377; = p.S289L on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1298281521, COSV60903447; called by muse, mutect2, varscan2
- RIMS2 | c.3253C>T p.R1085C (on ENST00000666250 / NM_001348490.2; = p.R893C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as rs1305079529, COSV51683394; called by muse, mutect2, varscan2
- SLC39A7 | c.1380_1382del p.I460del | In Frame Del (DEL) | VAF 15/107 reads (14%) | catalogued as rs774595475; called by mutect2, pindel, varscan2
- ST14 | c.272A>G p.N91S | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.164); catalogued as rs919359710; called by muse, mutect2, varscan2
- ACP2 | c.1005G>T p.K335N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.062); called by mutect2, varscan2
- ALKBH1 | c.663C>G p.Y221* | Nonsense Mutation (SNP) | VAF 16/192 reads (8%) | called by muse, mutect2
- ANKRD36 | c.4883C>G p.A1628G | Missense Mutation (SNP) | VAF 22/406 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.91); called by muse, mutect2
- ATP8A1 | c.2477C>T p.A826V | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- BANK1 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- CELF4 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CELSR2 | c.2459A>G p.Y820C | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPD | c.3661G>C p.D1221H | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DDX5 | c.412del p.A138Hfs*25 | Frame Shift Del (DEL) | VAF 21/154 reads (14%) | called by mutect2, pindel, varscan2
- DRC7 | c.248C>A p.S83Y | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FIGNL1 | c.1835G>T p.C612F | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- JSRP1 | c.964C>T p.Q322* | Nonsense Mutation (SNP) | VAF 3/20 reads (15%) | called by muse, varscan2
- MAP2K1 | c.413A>T p.E138V | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- MEX3A | c.488A>C p.N163T | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NT5C2 | c.1198G>T p.A400S | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.868); called by muse, mutect2
- PATJ | c.3785T>G p.M1262R | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- PCDH10 | c.480G>T p.E160D | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- PIGB | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- QKI | c.979C>A p.P327T | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XKR6 | c.85_114del p.E29_G38del | In Frame Del (DEL) | VAF 10/56 reads (18%) | called by mutect2, pindel
- CRTC2 | c.120C>T p.F40= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, varscan2
- FLII | c.1437C>A p.G479= | Silent (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- ICE1 | c.3030G>A p.V1010= | Silent (SNP) | VAF 16/177 reads (9%) | catalogued as COSV56827104; called by muse, mutect2
- IGHV3-64 | c.141C>T p.F47= | Silent (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2, varscan2
- INSYN2B | c.663C>T p.L221= | Silent (SNP) | VAF 20/176 reads (11%) | catalogued as COSV56954537; called by muse, mutect2, varscan2
- PGLYRP2 | c.1086C>T p.A362= | Silent (SNP) | VAF 8/89 reads (9%) | called by muse, mutect2, varscan2
- PSG1 | c.9C>A p.T3= | Silent (SNP) | VAF 27/179 reads (15%) | catalogued as COSV54944119; called by muse, mutect2, varscan2
- TIAM2 | c.279G>A p.T93= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs757270216, COSV59692875; called by muse, mutect2, varscan2
- ZNF394 | c.1683A>G p.L561= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs1463661588, COSV61793561; called by muse, mutect2
- GDPD2 | chrX:70434745 C>T | 3'Flank (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- OR2W5 | n.692G>A | RNA (SNP) | VAF 20/128 reads (16%) | catalogued as rs369336666; called by muse, mutect2, varscan2
